Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A6EX, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A6EX-01A (Primary Tumor).

Department of Cancer Pathology

Patient: XXX

Age:

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Gastric cancer.**

Date of admission:

Material:

1) Material: stomach, Method of collection: Multiple organ resection

Histopathological diagnosis

Examination performed on:

Poorly differentiated stomach adenocarcinoma.
(G3, pT3, pN2). (8140/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Specimen consisting of the stomach, having been cut out along the greater curvature, sized 22 x 17 cm with the omentum sized 42 x 28 cm.
Wall thickening with a ulceration in the middle in the pyloric region sized: 3,5 x 2,5 x 1,0 cm.
Distance from the proximal end: 16.5 cm, from distal end: 2.0 cm.

Microscopic description:

Poorly differentiated adenocarcinoma, partly tubular G3.
Cancer infiltrates the muscular wall and covers the fat tissue without invading the peritoneum.
Massive vascular invasion.
The omentum free of neoplastic lesions.
Surgical excision lines are within the area of healthy tissue.
Due to morphological traits indicative of endocrine differentiation.
Immunohistochemical tests in progress.
Lymph nodes:
3 - (lesser curvature): Lymphonodulitis reactiva No I.
4 - (greater curvature): Metastases carcinomatosae in lymphonodo No I/VII. Infiltratio carcinomatosa capsulae lymphonodorum lymphonodi et telae adiposae perinodalis.
6 - (peripyloric): Metastases carcinomatosae in lymphonodis No II/II. Infiltratio carcinomatosa capsulae lymphonodorum lymphonodi et telae adiposae perinodalis.
Cancerous deposits present.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Review and Initials	Date Reviewed: 5/20/13	

Source: NCI Genomic Data Commons file 95fd8d27-eed2-42ff-9e28-902158fc36f7 (TCGA-D7-A6EX.DB6157F1-ACB1-46AB-95EB-3B974173519A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).